Somatic mutation profile of tumor specimen TCGA-EM-A1CU-01A (aliquot TCGA-EM-A1CU-01A-11D-A13W-08) from TCGA case TCGA-EM-A1CU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.4 years (11,470 days).
Specimen TCGA-EM-A1CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6eba17f-64d7-4dac-b166-27696f656b27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1CU-10A (Blood Derived Normal), aliquot TCGA-EM-A1CU-10A-02D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ae0c7d3-bab4-4e28-8fe9-65005e622c72

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAMKV | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV56558093; called by muse, mutect2, varscan2
- CRYBG1 | c.5228G>T p.S1743I | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV64814937; called by muse, mutect2, varscan2
- H4C2 | c.150G>C p.L50F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs369387838, COSV55138372; called by muse, mutect2, varscan2
- HSPA8 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV57086863; called by muse, mutect2, varscan2
- MAGED1 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58517062; called by muse, mutect2, varscan2
- NCKAP1L | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV53212973; called by muse, mutect2
- TOGARAM2 | c.667T>A p.C223S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV65424135; called by muse, varscan2
- TSPAN14 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59370119; called by muse, mutect2
- DYNC1LI2 | c.1401del p.N467Kfs*9 | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- VAV2 | c.2291del p.K764Sfs*69 (on ENST00000371850 / NM_001134398.2; = p.K754Sfs*40 on NM_003371.4) | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- OAS3 | c.1479C>T p.R493= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as rs780870030, COSV57447520; called by muse, mutect2, varscan2
- PCDHGA12 | c.1839G>A p.E613= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV99342215; called by muse, mutect2, varscan2
